Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8382, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8382-01A (Primary Tumor).

[page 1 of 2]
Patient ID:

Surgical Date:

Gross Description: Stomach segment with the tumour in its lower third, of 7.5 cm in its largest dimension, with the whole wall invasion; omentum, fatty tissue are hyperemic; metastases are suspected.

Microscopic Description: Adenocarcinoma of the stomach, G3; with adjacent fatty tissue invasion and foci of necrosis.

Fifteen lymph nodes were examined, nine lymph nodes demonstrated metastases.

Omentum demonstrates metastases.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Antrum

Tumor size: 7.5 x 0 x 0 cm

Tumor features: Ulcerated

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Adjacent structures (specify) - Omentum

Lymph nodes: 9/15 positive for metastasis (Greater and lesser omentum 9/15)

Lymphatic invasion: Not specified

Venous invasion: Absent

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

10A-0-3

adenocarcinoma, NOS 8140/3

Site: antrum c16.3

hw
11/5/13

[page 2 of 2]
Comments: None

Source: NCI Genomic Data Commons file 354f425f-1040-45ee-a521-95ce53ca8dc3 (TCGA-BR-8382.F491D25F-25DB-43BD-8489-540FA929689E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).